Somatic mutation profile of tumor specimen ALCH-B1TB-TTP1-A (aliquot ALCH-B1TB-TTP1-A-3-0-D-A76B-36) from ALCHEMIST case ALCH-B1TB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.9 years (25,518 days).
Specimen ALCH-B1TB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca16945-5d6d-4ea3-a13d-993de3761241.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TB-NB1-A (Blood Derived Normal), aliquot ALCH-B1TB-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce60d926-cdb3-428c-8dc1-16ca73eff9b1

The open-access MAF lists 72 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 12, Nonsense Mutation 4, Intron 3, 3'UTR 3, 5'Flank 2, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL031777.2 | c.509G>C p.*170Sext*26 | Nonstop Mutation (SNP) | VAF 3/47 reads (6%) | catalogued as COSV61911923; called by muse, mutect2
- AMZ1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs776963117; called by muse, mutect2, varscan2
- CACNA1F | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CX158277; called by muse, mutect2
- CCDC141 | c.1978C>G p.R660G | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs1402528193, COSV55371699; called by muse, mutect2
- CCDC69 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.124); catalogued as rs774819545; called by muse, mutect2, varscan2
- CFH | c.2654G>T p.R885M | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1184020128, COSV66413521; called by muse, mutect2, varscan2
- DOCK11 | c.6188G>T p.R2063L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV52238991; called by muse, mutect2
- DPP6 | c.1837C>A p.P613T (on ENST00000377770 / NM_001364500.2; = p.P551T on NM_001936.5) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs868492054; called by muse, varscan2
- DYRK3 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1553420519; called by muse, mutect2, varscan2
- FCGBP | c.10793G>A p.R3598H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs754022836; called by muse, mutect2
- FCGR2B | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs777983386, COSV52682376; called by mutect2, varscan2
- FSIP2 | c.6637C>A p.R2213S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs550442160, COSV58092759; called by muse, mutect2, varscan2
- GRIN2B | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as rs1555133021, COSV74207843; called by muse, mutect2, varscan2
- GTPBP6 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV58204752; called by mutect2, varscan2
- KIF22 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV99361010; called by muse, mutect2
- LRRC72 | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1031428448; called by muse, mutect2
- MYH7 | c.4559G>T p.G1520V | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV62519205; called by muse, mutect2
- NLRP4 | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs148902972, COSV56719915; called by muse, mutect2, varscan2
- PIKFYVE | c.5326G>T p.G1776W | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52239393; called by muse, mutect2
- PKHD1 | c.5687C>T p.T1896M | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs140996978; called by muse, mutect2
- PYDC2 | c.130del p.Q44Rfs*4 | Frame Shift Del (DEL) | VAF 16/162 reads (10%) | catalogued as rs1348240779; called by mutect2, pindel
- SI | c.1273A>T p.I425F | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100014707; called by muse, mutect2
- SIM2 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.045); catalogued as rs1198987612; called by muse, varscan2
- THSD7B | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55712704; called by muse, mutect2
- TTC28 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1382012987; called by muse, mutect2
- ZDHHC17 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV58351580; called by muse, mutect2
- ACSL4 | c.780G>T p.L260F (on ENST00000340800 / NM_022977.2; = p.L219F on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.192); called by muse, mutect2
- BCLAF3 | c.974T>C p.F325S | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2
- CFAP54 | c.8373G>C p.Q2791H | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DNAH5 | c.4867G>T p.E1623* | Nonsense Mutation (SNP) | VAF 62/231 reads (27%) | called by muse, mutect2, varscan2
- FANCB | c.366G>C p.L122F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.976); called by muse, mutect2
- GABRB3 | c.868A>T p.N290Y | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- GLUD2 | c.1607C>G p.T536R | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- HMCN1 | c.6556A>G p.N2186D | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- HNF4A | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- KIAA1210 | c.3733G>T p.A1245S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- LAMA5 | c.3898G>T p.A1300S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, varscan2
- MTMR11 | c.67-8G>C | Splice Region (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- NLGN1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.044); called by muse, mutect2
- NUP155 | c.1843C>A p.P615T (on ENST00000231498 / NM_153485.3; = p.P556T on NM_004298.4) | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR4Q3 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2
- PARG | c.1730G>A p.W577* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | called by mutect2, varscan2
- PYROXD1 | c.625A>T p.K209* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- SMOC1 | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SNX7 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SYNE1 | c.11668G>T p.V3890F (on ENST00000367255 / NM_182961.4; = p.V3875F on NM_033071.3) | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2
- TMCO3 | c.1930C>T p.L644F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRAV8-4 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.441); called by muse, mutect2
- UNC80 | c.3396A>C p.E1132D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2
- VPS13A | c.7718A>T p.H2573L | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF398 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ANKRD52 | c.2958A>G p.T986= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- ARHGAP29 | c.1272C>T p.T424= | Silent (SNP) | VAF 25/318 reads (8%) | called by muse, mutect2
- ATP5F1D | c.366G>T p.L122= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- CAND1 | c.1014A>G p.E338= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2, varscan2
- CD96 | c.1311T>C p.S437= (on ENST00000283285 / NM_198196.3; = p.S421= on NM_005816.5) | Silent (SNP) | VAF 13/197 reads (7%) | catalogued as rs777210215; called by muse, mutect2
- DMD | c.5073C>A p.I1691= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- EGLN3 | c.555C>T p.L185= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as rs1487050157; called by muse, mutect2
- HDAC6 | c.501A>G p.L167= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- KCTD17 | c.393G>A p.K131= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- OR4S2 | c.609C>T p.T203= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV56748001; called by muse, mutect2, varscan2
- UVRAG | c.1932C>T p.A644= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2, varscan2
- YDJC | c.486G>A p.P162= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- AC092471.1 | n.689C>A | RNA (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- AKAP9 | c.5698-3015A>G | Intron (SNP) | VAF 19/205 reads (9%) | called by muse, mutect2
- BTK | chrX:101390550 G>T | 5'Flank (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- C5orf38 | c.*43T>G | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- CXorf65 | c.*1T>C | 3'UTR (SNP) | VAF 6/86 reads (7%) | catalogued as rs957025039; called by muse, mutect2
- GK | c.338-3538C>T | Intron (SNP) | VAF 10/116 reads (9%) | catalogued as rs1233988557; called by muse, mutect2
- GPR89B | c.728-482A>G | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- SNORD109A | chr15:25041963 G>T | 5'Flank (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- TMCO1 | c.*1321A>G | 3'UTR (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
